Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BS, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BS-01A (Primary Tumor).

	bw	10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

1C D-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS 073.9

h
10/15/11

TUMOR SITE:

Right lobe

Isthmus

Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 5.5 cm (isthmus and left thyroid lobe)

FOCALITY:

Multifocal

LYMPH NODES:

Metastatic carcinoma in 8 of 17 lymph nodes

EXTENT OF INVASION (7TH EDITION AJCC) PRIMARY TUMOR:

pT3:

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level V1 (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: Less than 1.0 mm

Specify margin: Anterior and posterior margins

VENOUS/LYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Other: One (1) parathyroid gland with adjacent thymic tissue.
(Inferior left thyroid lobe)

Source: NCI Genomic Data Commons file fd2b8005-cf62-45a9-a00b-5997e0be2914 (TCGA-ET-A3BS.15B854F2-949F-497F-B47D-C4DC3E8D9693.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).